Somatic mutation profile of tumor specimen ALCH-B2XG-TTP1-A (aliquot ALCH-B2XG-TTP1-A-1-0-D-A77K-36) from ALCHEMIST case ALCH-B2XG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.2 years (25,638 days).
Specimen ALCH-B2XG-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 840edab3-da64-4d09-ab31-8a0ac3361810.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2XG-NB1-A (Blood Derived Normal), aliquot ALCH-B2XG-NB1-A-1-0-D-A77K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2d8b9a0-be04-4ccc-b4de-c8e91b64f846

The open-access MAF lists 403 somatic variants for this specimen: 273 protein-altering or splice-affecting, 85 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 233, Silent 85, Intron 20, Nonsense Mutation 19, RNA 7, Frame Shift Del 7, 5'UTR 6, Splice Site 6, 3'UTR 5, Splice Region 5, 5'Flank 5, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 175/499 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 114/181 reads (63%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB5 | c.3697G>T p.E1233* (on ENST00000404938 / NM_001163941.2; = p.E788* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 14/364 reads (4%) | catalogued as COSV51723530; called by muse, mutect2
- ADAMTSL2 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1399670823; called by muse, mutect2, varscan2
- AHCTF1 | c.1847G>T p.R616L (on ENST00000366508; = p.R590L on NM_015446.5) | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV58253899; called by muse, mutect2, varscan2
- AHCTF1 | c.209G>T p.R70L (on ENST00000366508; = p.R44L on NM_015446.5) | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.535); catalogued as rs534814535, COSV58251944; called by muse, mutect2, varscan2
- AHNAK | c.2141A>G p.E714G | Missense Mutation (SNP) | VAF 91/282 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.774); catalogued as rs750052715; called by muse, mutect2, varscan2
- ATM | c.7039G>C p.E2347Q | Missense Mutation (SNP) | VAF 112/349 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV53723888; called by muse, mutect2, varscan2
- ATP8A2 | c.1912G>C p.E638Q | Missense Mutation (SNP) | VAF 80/131 reads (61%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as rs761854466; called by muse, mutect2, varscan2
- B3GNT3 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.11); catalogued as rs377576293; called by muse, mutect2, varscan2
- CCDC141 | c.3895C>A p.P1299T | Missense Mutation (SNP) | VAF 114/325 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as COSV55372517; called by muse, mutect2, varscan2
- CCDC39 | c.516G>T p.R172S | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.327); catalogued as COSV56492366; called by muse, mutect2, varscan2
- CD1A | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV56862072; called by mutect2, varscan2
- CDC42BPB | c.1123G>T p.D375Y | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63474463; called by muse, mutect2, varscan2
- CDH10 | c.590G>C p.R197T | Missense Mutation (SNP) | VAF 51/455 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100049909; called by muse, mutect2, varscan2
- CDH18 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 38/472 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.877); catalogued as COSV104386161; called by muse, mutect2
- CDH4 | c.2350G>A p.D784N | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1348705388; called by muse, mutect2, varscan2
- CDK18 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.237); catalogued as rs771603510; called by muse, mutect2
- CFAP91 | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV56340367; called by muse, mutect2, varscan2
- CHADL | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1293568485, COSV104369292; called by muse, mutect2, varscan2
- CHURC1 | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs548864634; called by muse, mutect2, varscan2
- CLVS1 | c.304C>A p.Q102K | Missense Mutation (SNP) | VAF 75/281 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as COSV57983522; called by muse, mutect2, varscan2
- CNTNAP2 | c.2461G>A p.A821T | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as rs375617946; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A1 | c.1789C>T p.R597C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs767374916, COSV65423461; called by muse, mutect2, varscan2
- CPS1 | c.2786G>A p.R929K | Missense Mutation (SNP) | VAF 91/307 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748045437; called by muse, mutect2, varscan2
- CPSF6 | c.1484G>T p.R495I | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs751208245, COSV57013535; called by muse, mutect2, varscan2
- CTAGE15 | c.1332G>T p.L444F | Missense Mutation (SNP) | VAF 38/376 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.22); catalogued as COSV101372143; called by muse, mutect2, varscan2
- CTNND2 | c.2566G>C p.E856Q | Missense Mutation (SNP) | VAF 75/572 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1169187498; called by muse, mutect2, varscan2
- DEPTOR | c.996G>T p.T332= | Splice Region (SNP) | VAF 65/265 reads (25%) | catalogued as rs778191053, COSV53812144, COSV99639031; called by muse, mutect2, varscan2
- DYNC2H1 | c.3998C>T p.A1333V | Missense Mutation (SNP) | VAF 95/392 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.378); catalogued as rs765156289; called by muse, mutect2, varscan2
- ELAPOR2 | c.2167G>A p.E723K (on ENST00000450689 / NM_001142749.3; = p.E556K on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV51889812, COSV51893064; called by muse, varscan2
- ENC1 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 96/176 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs1358617795; called by muse, mutect2, varscan2
- EPRS1 | c.1435-1G>T p.X479_splice | Splice Site (SNP) | VAF 80/283 reads (28%) | catalogued as COSV65098766; called by muse, mutect2, varscan2
- FAM177B | c.12del p.D4Efs*6 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as COSV62600965; called by mutect2, pindel, varscan2
- FAM207A | c.366A>G p.I122M | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs1400970920; called by muse, mutect2, varscan2
- FCER2 | c.137-4C>T | Splice Region (SNP) | VAF 16/35 reads (46%) | catalogued as rs758197012; called by muse, mutect2, varscan2
- FNTB | c.95G>C p.R32P | Missense Mutation (SNP) | VAF 126/283 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.136); catalogued as COSV99862875, COSV99863151; called by muse, mutect2, varscan2
- FRAS1 | c.1849G>T p.G617W | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376269266; called by muse, mutect2, varscan2
- FRY | c.2834C>T p.A945V | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as rs1227588645, COSV100969660; called by muse, mutect2, varscan2
- FSIP2 | c.12619G>A p.G4207R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as rs1294796270; called by muse, mutect2, varscan2
- GAS2L2 | c.1882G>A p.G628R | Missense Mutation (SNP) | VAF 88/135 reads (65%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as rs971140873; called by muse, mutect2, varscan2
- GGT5 | c.883A>G p.I295V | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as rs1199287575; called by muse, mutect2, varscan2
- GPC5 | c.596G>C p.R199P | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100994380, COSV65617949; called by muse, mutect2, varscan2
- HCN1 | c.1024G>T p.G342* | Nonsense Mutation (SNP) | VAF 253/970 reads (26%) | catalogued as COSV57496654; called by muse, mutect2, varscan2
- HEY2 | c.746G>A p.C249Y | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs747415627; called by muse, mutect2, varscan2
- HMMR | c.76G>T p.V26F | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV57085377; called by muse, mutect2, varscan2
- HRG | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 42/425 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs529521530, COSV51644141; called by muse, mutect2, varscan2
- IGSF11 | c.985C>T p.H329Y (on ENST00000393775 / NM_001015887.3; = p.H328Y on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 173/509 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV100677311, COSV61174390; called by muse, mutect2, varscan2
- IL18RAP | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV51825660; called by muse, mutect2, varscan2
- KANK3 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs761573919; called by muse, mutect2, varscan2
- KHSRP | c.1485C>G p.I495M | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs769685889, COSV67919464; called by muse, mutect2, varscan2
- KIAA1958 | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.789); catalogued as rs562492705, COSV61725124, COSV61728491; called by muse, mutect2
- L3MBTL1 | c.2185G>T p.D729Y (on ENST00000418998 / NM_001377303.1; = p.D639Y on NM_015478.7) | Missense Mutation (SNP) | VAF 121/212 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV64229558; called by muse, mutect2, varscan2
- LAMP5 | c.818G>A p.R273K | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55717944; called by muse, mutect2, varscan2
- LCORL | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 19/77 reads (25%) | catalogued as rs1190510160; called by muse, mutect2, varscan2
- LILRA6 | c.539T>C p.L180P | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1487121543; called by muse, mutect2, varscan2
- LONP1 | c.2785G>A p.E929K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as rs758265405; called by muse, mutect2, varscan2
- LRRC17 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as COSV99978330; called by muse, mutect2, varscan2
- LRRC4 | c.1954C>G p.Q652E | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1302000934; called by muse, mutect2, varscan2
- LRTM2 | c.416C>G p.S139W | Missense Mutation (SNP) | VAF 82/135 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV54564410, COSV54564443, COSV99765395; called by muse, mutect2, varscan2
- MATK | c.1366C>G p.L456V (on ENST00000310132 / NM_139355.3; = p.L457V on NM_002378.4) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.745); catalogued as COSV59556468; called by mutect2, varscan2
- MED17 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as rs768892538; called by muse, mutect2, varscan2
- MFN1 | c.140G>C p.R47P | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.229); catalogued as COSV54938048; called by muse, mutect2, varscan2
- MOB1B | c.409+1G>A p.X137_splice | Splice Site (SNP) | VAF 24/131 reads (18%) | catalogued as COSV100511435; called by muse, mutect2, varscan2
- MUC16 | c.7025C>A p.S2342* | Nonsense Mutation (SNP) | VAF 35/124 reads (28%) | catalogued as COSV67467094; called by muse, mutect2, varscan2
- MYO15A | c.4606C>T p.R1536* | Nonsense Mutation (SNP) | VAF 75/288 reads (26%) | catalogued as rs371352951; called by muse, mutect2, varscan2
- MYO3A | c.4012C>A p.P1338T | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as rs1264669872; called by muse, mutect2, varscan2
- NAA16 | c.620A>G p.Q207R | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV65065001; called by muse, mutect2, varscan2
- NEUROG2 | c.401C>A p.A134E | Missense Mutation (SNP) | VAF 69/247 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.234); catalogued as rs1400053946; called by muse, mutect2, varscan2
- NRXN2 | c.3071C>A p.T1024K | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs757534789, COSV55447700; called by muse, mutect2, varscan2
- OOSP2 | c.307C>A p.H103N | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV53928101, COSV53928724; called by muse, mutect2, varscan2
- OR10Q1 | c.96C>A p.F32L | Missense Mutation (SNP) | VAF 66/239 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57470343; called by muse, mutect2, varscan2
- OR10T2 | c.781C>G p.R261G | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV57780839; called by muse, mutect2, varscan2
- OR4A5 | c.690G>T p.R230S | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as rs1443925966, COSV60524635; called by muse, mutect2
- OR4C12 | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.633); catalogued as rs782487839; called by muse, mutect2, varscan2
- PAK4 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs1189702999, COSV100426499; called by muse, mutect2
- PCDH15 | c.2116G>A p.V706M | Missense Mutation (SNP) | VAF 105/248 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV57267086; called by muse, mutect2, varscan2
- PKHD1L1 | c.12310G>T p.V4104L | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV65736898; called by muse, mutect2, varscan2
- POTEC | c.102C>A p.C34* | Nonsense Mutation (SNP) | VAF 78/245 reads (32%) | catalogued as COSV100743938; called by muse, mutect2, varscan2
- POTEM | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 77/787 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.292); catalogued as rs1267672814; called by muse, mutect2, varscan2
- PRKCD | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.4); catalogued as rs1057518393; ClinVar: uncertain significance; called by muse, varscan2
- PRKDC | c.2627C>G p.S876* | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | catalogued as COSV100042897; called by muse, mutect2, varscan2
- PRKDC | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.529); catalogued as COSV58067622; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1249G>T p.E417* (on ENST00000352766; = p.E338* on NM_181334.5) | Nonsense Mutation (SNP) | VAF 64/213 reads (30%) | catalogued as COSV61231879; called by muse, mutect2, varscan2
- REG3A | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs190335034, COSV59412327; called by muse, mutect2, varscan2
- RP1L1 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as COSV66755643; called by muse, mutect2, varscan2
- SCYL2 | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.323); catalogued as COSV62571111; called by muse, mutect2, varscan2
- SIN3B | c.2786G>A p.R929H | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.511); catalogued as rs779393264, COSV56134544; called by muse, mutect2, varscan2
- SLC28A1 | c.1211A>G p.Y404C | Missense Mutation (SNP) | VAF 90/150 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1227929735; called by muse, mutect2, varscan2
- SNX6 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.069); catalogued as rs945339499; called by muse, mutect2, varscan2
- SPATA25 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs761392675; called by muse, mutect2, varscan2
- SPATA48 | c.604C>G p.R202G | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs773612283; called by muse, mutect2, varscan2
- SPEG | c.5692C>T p.R1898W | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs759451461; called by muse, mutect2, varscan2
- SPIN3 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 53/71 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV66528909; called by muse, mutect2, varscan2
- SPRY2 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.996); catalogued as rs778275764; called by muse, mutect2, varscan2
- TALDO1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.362); catalogued as rs745474457; called by muse, mutect2, varscan2
- TARS1 | c.1142G>T p.R381L | Missense Mutation (SNP) | VAF 238/782 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV54308736; called by muse, mutect2, varscan2
- TLN2 | c.1667G>A p.G556E | Missense Mutation (SNP) | VAF 112/167 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780364585, COSV60891734, COSV60893860; called by muse, mutect2, varscan2
- TRIM51GP | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 164/641 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1274576573; called by muse, mutect2, varscan2
- TTPA | c.700C>T p.L234F | Missense Mutation (SNP) | VAF 95/309 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.246); catalogued as COSV52648355; called by muse, mutect2, varscan2
- UGT2B4 | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs558607262; called by muse, mutect2, varscan2
- WDR81 | c.3097G>A p.E1033K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.783); catalogued as rs754545737; called by muse, mutect2, varscan2
- ZIC1 | c.1194C>A p.S398R | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99291564; called by muse, mutect2, varscan2
- ZNF250 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 68/245 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs368079750; called by muse, mutect2, varscan2
- ZNF740 | c.7C>A p.Q3K | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.92); PolyPhen benign (0.292); catalogued as COSV99914473; called by muse, mutect2, varscan2
- ACTRT3 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 80/394 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM22 | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 42/277 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAMTS12 | c.4084C>A p.L1362I | Missense Mutation (SNP) | VAF 82/327 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ADCK1 | c.114G>T p.R38S | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRD1 | c.410G>T p.C137F | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- AFAP1L2 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- AMN | c.430T>A p.F144I | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ANKMY1 | c.2470C>T p.Q824* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- ANKRD12 | c.4174A>T p.T1392S | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD24 | c.3174C>G p.I1058M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATP13A3 | c.3067T>A p.L1023M | Missense Mutation (SNP) | VAF 155/935 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP2B3 | c.2842G>C p.E948Q | Missense Mutation (SNP) | VAF 52/72 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- BMS1 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- BTN3A3 | c.91T>G p.F31V | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- C1orf167 | c.2323G>T p.G775C | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- C2CD5 | c.344T>C p.I115T | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- C4orf46 | c.233C>G p.S78* | Nonsense Mutation (SNP) | VAF 89/269 reads (33%) | called by muse, mutect2, varscan2
- CABIN1 | c.5646G>C p.E1882D | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CACNA2D3 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 76/146 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- CCDC168 | c.5768A>G p.D1923G | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDK12 | c.916A>G p.S306G | Missense Mutation (SNP) | VAF 84/147 reads (57%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK8 | c.654G>T p.W218C | Missense Mutation (SNP) | VAF 85/158 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CFAP46 | c.6806T>A p.L2269Q | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CHRNB1 | c.413C>G p.S138C | Missense Mutation (SNP) | VAF 144/324 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CPXCR1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CTAGE15 | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 37/381 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- CTNNA2 | c.2763G>T p.K921N (on ENST00000402739 / NM_001282597.3; = p.K873N on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- DNAH5 | c.12961G>T p.D4321Y | Missense Mutation (SNP) | VAF 369/1072 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH6 | c.561G>T p.L187F | Missense Mutation (SNP) | VAF 87/355 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DNAH9 | c.5072T>C p.V1691A | Missense Mutation (SNP) | VAF 109/182 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- DPP3 | c.142G>T p.V48L | Missense Mutation (SNP) | VAF 97/300 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EFCAB13 | c.900G>T p.L300F | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- EIF2S3 | c.798A>T p.K266N | Missense Mutation (SNP) | VAF 116/178 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ENC1 | c.1496del p.G499Vfs*26 | Frame Shift Del (DEL) | VAF 66/173 reads (38%) | called by mutect2, pindel, varscan2
- EPRS1 | c.1435G>T p.G479C | Missense Mutation (SNP) | VAF 83/288 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F8 | c.3054G>C p.K1018N | Missense Mutation (SNP) | VAF 47/69 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- FAM184A | c.2308G>C p.E770Q | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAT3 | c.12218G>C p.G4073A | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- FCRL4 | c.110G>C p.G37A | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FER1L5 | c.4440C>A p.G1480= (on ENST00000623019; = p.G1453= on NM_001293083.2) | Splice Region (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2
- FOXL2 | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FREM2 | c.4969C>G p.Q1657E | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- GATA6 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- GDF10 | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- GOLGB1 | c.2988G>T p.Q996H | Missense Mutation (SNP) | VAF 66/227 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GPR152 | c.694T>C p.C232R | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- GYS2 | c.1822G>T p.A608S | Missense Mutation (SNP) | VAF 116/599 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEPHL1 | c.2620C>A p.P874T | Missense Mutation (SNP) | VAF 106/364 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGHA2 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 31/130 reads (24%) | called by muse, mutect2, varscan2
- IGHG4 | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 56/209 reads (27%) | called by muse, mutect2, varscan2
- IGHG4 | c.705G>T p.Q235H | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- IGHV1-3 | c.8G>A p.W3* | Nonsense Mutation (SNP) | VAF 96/274 reads (35%) | called by muse, mutect2, varscan2
- IGHV4-61 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 87/272 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- IGSF11 | c.238C>A p.Q80K (on ENST00000393775 / NM_001015887.3; = p.Q79K on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- ITGA3 | c.1902G>T p.E634D | Missense Mutation (SNP) | VAF 80/133 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ITPA | c.321C>G p.F107L | Missense Mutation (SNP) | VAF 87/219 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- KANSL1 | c.3286G>T p.A1096S (on ENST00000574590 / NM_001193465.2; = p.A1097S on NM_015443.4) | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- KCNB2 | c.833A>G p.Y278C | Missense Mutation (SNP) | VAF 95/322 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KEL | c.2192T>A p.L731H | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLF15 | c.547C>A p.H183N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by mutect2, varscan2
- KLHL25 | c.92G>C p.C31S | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL7 | c.937G>T p.D313Y (on ENST00000339077 / NM_001031710.3; = p.D265Y on NM_018846.5) | Missense Mutation (SNP) | VAF 94/331 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- KRTAP10-1 | c.482C>G p.S161C | Missense Mutation (SNP) | VAF 121/357 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- KRTAP19-7 | c.43T>A p.C15S | Missense Mutation (SNP) | VAF 75/253 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- LARP4 | c.657C>G p.F219L | Missense Mutation (SNP) | VAF 87/171 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LCE1A | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 104/446 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- LCE1A | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 110/446 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- LRRC29 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.048); called by muse, mutect2
- LRRC37A3 | c.3047A>T p.E1016V | Missense Mutation (SNP) | VAF 138/285 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- LRRC3B | c.233C>A p.S78Y | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LRRFIP2 | c.1913C>G p.S638* | Nonsense Mutation (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- LRRTM1 | c.847C>A p.Q283K | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEL2 | c.1838A>T p.Q613L | Missense Mutation (SNP) | VAF 70/119 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- MAGEL2 | c.770C>G p.A257G | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MAPK10 | c.53C>G p.S18* (on ENST00000359221 / NM_001351625.2; = p.S56* on NM_002753.5) | Nonsense Mutation (SNP) | VAF 75/222 reads (34%) | called by muse, mutect2, varscan2
- MAST1 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 102/305 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MDH2 | c.238T>A p.Y80N | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- MPHOSPH10 | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- MS4A10 | c.715C>A p.H239N | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC17 | c.1227G>T p.E409D | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC17 | c.1228G>T p.A410S | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- MUC19 | c.599G>C p.S200T | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- MYO15B | c.4505_4518del p.S1502Ifs*17 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | called by mutect2, pindel, varscan2
- NELL1 | c.2045G>A p.C682Y | Missense Mutation (SNP) | VAF 73/158 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NLRP8 | c.2394del p.L799Wfs*20 | Frame Shift Del (DEL) | VAF 30/65 reads (46%) | called by mutect2, pindel, varscan2
- NOP14 | c.1499+7A>G | Splice Region (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- NRXN3 | c.2936T>C p.V979A (on ENST00000335750 / NM_001330195.2; = p.V606A on NM_004796.6) | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NSMAF | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NTM | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NTRK3 | c.527A>G p.E176G | Missense Mutation (SNP) | VAF 65/114 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NUAK2 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP205 | c.5732A>T p.Y1911F | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- OBP2B | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- OR10S1 | c.416C>G p.A139G | Missense Mutation (SNP) | VAF 94/292 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- OR11H1 | c.460G>T p.V154F | Missense Mutation (SNP) | VAF 74/233 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.093); called by mutect2, varscan2
- OR13C9 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR4C5 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 118/340 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR5L2 | c.530T>A p.F177Y | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- OR6V1 | c.125T>C p.I42T | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- P2RY12 | c.786C>G p.S262R | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PARP15 | c.148dup p.A50Gfs*90 | Frame Shift Ins (INS) | VAF 12/54 reads (22%) | called by mutect2, pindel, varscan2
- PCDH9 | c.3319G>T p.G1107C (on ENST00000377865 / NM_203487.3; = p.G1073C on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/157 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDK1 | c.731A>G p.Y244C | Missense Mutation (SNP) | VAF 84/342 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLA2R1 | c.218G>T p.W73L | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLRG1 | c.1046G>A p.S349N | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLM | c.704A>G p.Q235R | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- POU3F1 | c.1225G>T p.D409Y | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- POU6F2 | c.775A>G p.N259D | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PPFIA3 | c.2717C>T p.S906L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- PPP1R21 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 83/296 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRSS54 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PTPRM | c.850C>G p.P284A | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PUS7L | c.273_276del p.I92Sfs*33 | Frame Shift Del (DEL) | VAF 48/166 reads (29%) | called by mutect2, pindel, varscan2
- RAB36 | c.21C>A p.S7R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- RELN | c.2070G>T p.K690N | Missense Mutation (SNP) | VAF 121/425 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RELN | c.2070-1G>T p.X690_splice | Splice Site (SNP) | VAF 120/421 reads (29%) | called by muse, mutect2, varscan2
- RIBC2 | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 91/252 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- RIBC2 | c.864G>C p.Q288H | Missense Mutation (SNP) | VAF 77/198 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RIMS2 | c.1427C>T p.T476I (on ENST00000666250 / NM_001348490.2; = p.T284I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 177/694 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SEL1L2 | c.1737C>A p.S579R | Missense Mutation (SNP) | VAF 112/439 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SERTAD4 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 21/161 reads (13%) | called by muse, mutect2, varscan2
- SEZ6L | c.637C>G p.H213D | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SHLD3 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- SLC25A37 | c.531G>T p.Q177H | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2
- SLC35F2 | c.284C>G p.S95* | Nonsense Mutation (SNP) | VAF 18/96 reads (19%) | called by muse, mutect2, varscan2
- SLC43A1 | c.559-1G>T p.X187_splice | Splice Site (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- SLC6A12 | c.1161G>C p.M387I | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC6A18 | c.1247C>A p.S416* | Nonsense Mutation (SNP) | VAF 137/190 reads (72%) | called by muse, mutect2, varscan2
- SLC6A9 | c.145C>G p.P49A | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLCO1A2 | c.1709T>C p.L570S | Missense Mutation (SNP) | VAF 163/380 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- SLCO5A1 | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SMG1 | c.5722C>G p.Q1908E | Missense Mutation (SNP) | VAF 134/240 reads (56%) | SIFT tolerated (1); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- STAB1 | c.4504C>G p.L1502V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SUFU | c.182+1G>C p.X61_splice | Splice Site (SNP) | VAF 57/107 reads (53%) | called by muse, mutect2, varscan2
- TBC1D22B | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TBCE | c.1039G>A p.E347K (on ENST00000366601; = p.E410K on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/361 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- TDP1 | c.-7G>T | Splice Region (SNP) | VAF 119/358 reads (33%) | called by muse, mutect2, varscan2
- TENM3 | c.569A>G p.K190R | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TLN2 | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 158/223 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, varscan2
- TPTE | c.512T>C p.L171P (on ENST00000618007 / NM_199261.4; = p.L153P on NM_199259.4) | Missense Mutation (SNP) | VAF 58/446 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRAV12-3 | c.163T>C p.F55L | Missense Mutation (SNP) | VAF 72/269 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- TRAV17 | c.225G>C p.E75D | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- TRIM51GP | c.1042G>T p.G348W | Missense Mutation (SNP) | VAF 163/640 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TRIM64 | c.265_266del p.D89Qfs*7 | Frame Shift Del (DEL) | VAF 18/27 reads (67%) | called by mutect2, varscan2
- TRIM64C | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 117/469 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- TRPM5 | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TRRAP | c.5413G>C p.E1805Q (on ENST00000359863 / NM_001244580.1; = p.E1787Q on NM_003496.3) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- TTLL5 | c.2440G>A p.A814T | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTN | c.80172C>G p.D26724E (on ENST00000591111; = p.D19300E on NM_003319.4) | Missense Mutation (SNP) | VAF 60/208 reads (29%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTN | c.15704C>T p.S5235L (on ENST00000591111; = p.S4308L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | PolyPhen benign (0.121); called by muse, mutect2, varscan2
- TTN | c.7458G>T p.K2486N (on ENST00000591111; = p.K2440N on NM_003319.4) | Missense Mutation (SNP) | VAF 122/402 reads (30%) | PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- TUBGCP3 | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBA6 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- UBQLN3 | c.416G>C p.G139A | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- USH2A | c.15400C>A p.L5134I | Missense Mutation (SNP) | VAF 117/295 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- USP20 | c.1838G>C p.R613P | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- USP40 | c.2185C>A p.H729N | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWA8 | c.1892C>G p.A631G | Missense Mutation (SNP) | VAF 139/266 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDFY4 | c.5588C>A p.A1863D | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- WDR37 | c.955C>G p.L319V | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); called by muse, varscan2
- WWC3 | c.1858dup p.H620Pfs*50 | Frame Shift Ins (INS) | VAF 33/62 reads (53%) | called by mutect2, pindel, varscan2
- ZBTB24 | c.151_160del p.H51Yfs*11 | Frame Shift Del (DEL) | VAF 71/167 reads (43%) | called by mutect2, pindel, varscan2
- ZEB1 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 96/220 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ZFHX4 | c.8821C>G p.L2941V | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- ZNF169 | c.615C>G p.D205E | Missense Mutation (SNP) | VAF 61/100 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF443 | c.1756A>G p.K586E | Missense Mutation (SNP) | VAF 88/267 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ZNF98 | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ZSCAN26 | c.833G>A p.R278K (on ENST00000623276 / NM_001111039.2; = p.R144K on NM_152736.5) | Missense Mutation (SNP) | VAF 69/147 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACCSL | c.1512T>C p.Y504= | Silent (SNP) | VAF 16/109 reads (15%) | called by muse, mutect2, varscan2
- ADAM18 | c.801G>T p.R267= | Silent (SNP) | VAF 25/147 reads (17%) | catalogued as COSV55848669; called by muse, mutect2, varscan2
- ADAM18 | c.2010G>A p.Q670= | Silent (SNP) | VAF 34/181 reads (19%) | called by muse, mutect2, varscan2
- ADGRA1 | c.120C>T p.I40= | Silent (SNP) | VAF 43/76 reads (57%) | catalogued as rs751844986, COSV66930793; called by muse, mutect2, varscan2
- AFG3L2 | c.1419C>A p.I473= | Silent (SNP) | VAF 105/628 reads (17%) | called by muse, mutect2, varscan2
- ANKRD33B | c.1257C>T p.P419= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1460984188; called by muse, mutect2, varscan2
- ARHGAP45 | c.1965G>T p.T655= | Silent (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- ASGR2 | c.567C>T p.Y189= | Silent (SNP) | VAF 59/98 reads (60%) | called by muse, mutect2, varscan2
- ATXN7L3 | c.450G>A p.K150= | Silent (SNP) | VAF 72/153 reads (47%) | catalogued as COSV66988596; called by muse, mutect2, varscan2
- B3GAT1 | c.525C>T p.R175= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV56999788; called by muse, mutect2, varscan2
- BCL9 | c.3336C>A p.G1112= | Silent (SNP) | VAF 97/197 reads (49%) | called by muse, mutect2, varscan2
- BRINP1 | c.1857A>C p.L619= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV56311955; called by muse, mutect2, varscan2
- BRWD1 | c.2646A>G p.T882= | Silent (SNP) | VAF 56/192 reads (29%) | catalogued as rs749390150; called by muse, mutect2, varscan2
- CALB1 | c.117G>A p.L39= | Silent (SNP) | VAF 84/391 reads (21%) | called by muse, mutect2, varscan2
- CD1A | c.594C>A p.L198= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV56860233, COSV99192591; called by muse, mutect2, varscan2
- CD276 | c.1413G>T p.V471= (on ENST00000318443 / NM_001024736.2; = p.V253= on NM_025240.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 90/152 reads (59%) | called by muse, mutect2, varscan2
- CD33 | c.753A>G p.Q251= | Silent (SNP) | VAF 69/161 reads (43%) | catalogued as rs370402568, COSV51800911; called by muse, mutect2, varscan2
- CEBPA | c.753C>T p.S251= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs1364096520; called by mutect2, varscan2
- CEP250 | c.4791A>G p.L1597= | Silent (SNP) | VAF 77/132 reads (58%) | called by muse, mutect2, varscan2
- CHRNA9 | c.714G>T p.S238= | Silent (SNP) | VAF 65/148 reads (44%) | catalogued as rs373265892, COSV59573719; called by muse, mutect2, varscan2
- COL25A1 | c.114G>T p.A38= | Silent (SNP) | VAF 41/122 reads (34%) | catalogued as COSV101211347; called by muse, mutect2, varscan2
- DENND10 | c.792C>T p.P264= | Silent (SNP) | VAF 53/95 reads (56%) | catalogued as rs963726133; called by muse, mutect2, varscan2
- DENND1B | c.390C>T p.L130= | Silent (SNP) | VAF 81/243 reads (33%) | catalogued as COSV52463924, COSV52469151; called by muse, mutect2, varscan2
- DMD | c.9618G>T p.L3206= | Silent (SNP) | VAF 98/163 reads (60%) | called by muse, mutect2, varscan2
- DNAH9 | c.10026A>G p.A3342= | Silent (SNP) | VAF 73/129 reads (57%) | called by muse, mutect2, varscan2
- DSG3 | c.1986A>T p.S662= | Silent (SNP) | VAF 120/348 reads (34%) | called by muse, mutect2, varscan2
- EML5 | c.3306C>A p.S1102= | Silent (SNP) | VAF 82/324 reads (25%) | catalogued as COSV61352170; called by muse, mutect2, varscan2
- F2RL1 | c.792G>A p.L264= | Silent (SNP) | VAF 39/96 reads (41%) | called by muse, mutect2, varscan2
- FBN3 | c.4137C>T p.L1379= | Silent (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- FBN3 | c.3786C>T p.V1262= | Silent (SNP) | VAF 51/140 reads (36%) | called by muse, mutect2, varscan2
- FMN1 | c.240G>T p.T80= | Silent (SNP) | VAF 88/162 reads (54%) | called by muse, mutect2, varscan2
- FRRS1 | c.1185C>T p.F395= | Silent (SNP) | VAF 66/180 reads (37%) | called by muse, mutect2, varscan2
- FSTL4 | c.675C>T p.D225= | Silent (SNP) | VAF 74/139 reads (53%) | catalogued as rs147434496; called by muse, mutect2, varscan2
- GPI | c.1509C>A p.I503= | Silent (SNP) | VAF 49/251 reads (20%) | called by muse, mutect2, varscan2
- GPR75 | c.495C>G p.T165= | Silent (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- GRIN3B | c.900G>T p.V300= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- HMCN2 | c.5742G>A p.E1914= | Silent (SNP) | VAF 27/42 reads (64%) | called by muse, mutect2, varscan2
- HMGCR | c.1095A>T p.P365= | Silent (SNP) | VAF 131/303 reads (43%) | called by muse, mutect2, varscan2
- HUWE1 | c.11922G>T p.T3974= | Silent (SNP) | VAF 108/151 reads (72%) | called by muse, mutect2, varscan2
- ILDR1 | c.333C>A p.P111= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as COSV56550788; called by muse, mutect2, varscan2
- ITIH5 | c.222G>T p.L74= | Silent (SNP) | VAF 54/159 reads (34%) | called by muse, mutect2, varscan2
- KANSL1 | c.3285A>C p.A1095= (on ENST00000574590 / NM_001193465.2; = p.A1096= on NM_015443.4) | Silent (SNP) | VAF 28/48 reads (58%) | called by muse, mutect2, varscan2
- KLF5 | c.603A>G p.P201= | Silent (SNP) | VAF 38/175 reads (22%) | called by muse, mutect2, varscan2
- KRTAP12-1 | c.48G>A p.A16= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as rs782395683, COSV59969608; called by muse, mutect2, varscan2
- LGMN | c.1038G>A p.E346= | Silent (SNP) | VAF 39/89 reads (44%) | called by muse, mutect2, varscan2
- LIX1L | c.477G>A p.E159= | Silent (SNP) | VAF 145/276 reads (53%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.18C>G p.V6= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as COSV63048015; called by muse, mutect2, varscan2
- MAGEA6 | c.675G>C p.L225= | Silent (SNP) | VAF 104/150 reads (69%) | catalogued as rs141848261, COSV61449386; called by muse, mutect2, varscan2
- NKX3-2 | c.39C>T p.S13= | Silent (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- OR10H3 | c.198C>T p.A66= | Silent (SNP) | VAF 62/190 reads (33%) | catalogued as rs1455221288; called by muse, mutect2
- OR10J1 | c.135T>A p.I45= | Silent (SNP) | VAF 161/311 reads (52%) | called by muse, mutect2, varscan2
- OR2M5 | c.75C>T p.T25= | Silent (SNP) | VAF 23/144 reads (16%) | called by muse, mutect2, varscan2
- OR2T6 | c.129G>A p.G43= | Silent (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2, varscan2
- OR5D13 | c.645C>A p.I215= | Silent (SNP) | VAF 76/233 reads (33%) | catalogued as COSV62332602, COSV62335106; called by muse, mutect2, varscan2
- PAPOLA | c.78C>T p.I26= | Silent (SNP) | VAF 63/224 reads (28%) | called by muse, mutect2, varscan2
- PCDHA9 | c.1593A>G p.L531= | Silent (SNP) | VAF 99/211 reads (47%) | catalogued as rs782057143; called by muse, mutect2, varscan2
- PCDHB2 | c.303A>G p.T101= | Silent (SNP) | VAF 56/120 reads (47%) | called by muse, mutect2, varscan2
- PCDHB7 | c.1878C>A p.T626= | Silent (SNP) | VAF 109/214 reads (51%) | catalogued as rs1352310001, COSV50758107; called by muse, mutect2, varscan2
- PDCD6 | c.63G>A p.A21= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs1284162594; called by muse, mutect2, varscan2
- PEG3 | c.2811T>C p.A937= | Silent (SNP) | VAF 44/73 reads (60%) | called by muse, mutect2, varscan2
- PIK3C2A | c.2784C>T p.Y928= | Silent (SNP) | VAF 81/122 reads (66%) | called by muse, mutect2, varscan2
- POGK | c.1599G>C p.L533= | Silent (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- POTEM | c.201C>T p.H67= | Silent (SNP) | VAF 101/702 reads (14%) | catalogued as rs570992749; called by muse, varscan2
- PPP1R32 | c.1026G>C p.L342= | Silent (SNP) | VAF 55/165 reads (33%) | called by muse, mutect2, varscan2
- PTGDR2 | c.354C>T p.S118= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as rs752596038; called by muse, mutect2, varscan2
- RGMA | c.219C>T p.P73= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs766430068, COSV100224438; called by muse, mutect2, varscan2
- RIPK3 | c.312G>A p.G104= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as rs1190713880; called by muse, mutect2, varscan2
- RIPOR2 | c.2829C>G p.L943= | Silent (SNP) | VAF 191/342 reads (56%) | called by muse, mutect2, varscan2
- RNF25 | c.126A>G p.P42= | Silent (SNP) | VAF 39/128 reads (30%) | called by muse, mutect2, varscan2
- RPS16 | c.276G>T p.L92= | Silent (SNP) | VAF 17/98 reads (17%) | called by muse, mutect2
- SLC27A5 | c.1821C>T p.F607= | Silent (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- SP140 | c.1978C>T p.L660= | Silent (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- SPAG1 | c.225G>A p.L75= | Silent (SNP) | VAF 85/382 reads (22%) | catalogued as COSV52561521; called by muse, mutect2, varscan2
- SREBF1 | c.3108C>T p.F1036= | Silent (SNP) | VAF 43/86 reads (50%) | called by muse, mutect2, varscan2
- TBC1D9 | c.453G>C p.L151= | Silent (SNP) | VAF 90/311 reads (29%) | catalogued as rs1317216860; called by muse, mutect2, varscan2
- TMEM183A | c.987G>A p.V329= | Silent (SNP) | VAF 22/147 reads (15%) | called by muse, mutect2, varscan2
- TRABD2A | c.75G>T p.A25= | Silent (SNP) | VAF 50/162 reads (31%) | catalogued as rs534782823, COSV59102161; called by muse, mutect2, varscan2
- TTN | c.50595T>C p.D16865= (on ENST00000591111; = p.D9441= on NM_003319.4) | Silent (SNP) | VAF 60/169 reads (36%) | catalogued as rs1366995927; called by muse, mutect2, varscan2
- TULP4 | c.2985G>T p.T995= | Silent (SNP) | VAF 12/13 reads (92%) | catalogued as COSV100893758; called by muse, mutect2, varscan2
- UGT2B11 | c.1251C>T p.F417= | Silent (SNP) | VAF 140/451 reads (31%) | called by muse, mutect2, varscan2
- UIMC1 | c.1518G>T p.P506= | Silent (SNP) | VAF 89/185 reads (48%) | called by muse, mutect2, varscan2
- ZFHX4 | c.4555C>A p.R1519= | Silent (SNP) | VAF 68/163 reads (42%) | called by muse, mutect2, varscan2
- ZFP42 | c.753G>T p.G251= | Silent (SNP) | VAF 105/252 reads (42%) | catalogued as rs767291029; called by muse, mutect2, varscan2
- ZNF648 | c.1437G>A p.T479= | Silent (SNP) | VAF 52/203 reads (26%) | called by muse, mutect2, varscan2
- ZSWIM8 | c.954C>T p.S318= | Silent (SNP) | VAF 43/75 reads (57%) | catalogued as COSV67132589; called by muse, mutect2, varscan2
- ANKRD20A8P | n.567C>A | RNA (SNP) | VAF 49/309 reads (16%) | called by muse, mutect2, varscan2
- ANKRD42 | chr11:83194284 G>A | 5'Flank (SNP) | VAF 37/151 reads (25%) | called by muse, mutect2, varscan2
- APLP1 | c.292-25G>C | Intron (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2, varscan2
- C8orf82 | c.-143G>C | 5'UTR (SNP) | VAF 7/21 reads (33%) | catalogued as rs930189115; called by muse, mutect2, varscan2
- CADM1 | chr11:115504434 C>G | 5'Flank (SNP) | VAF 8/64 reads (13%) | catalogued as rs569904645; called by muse, mutect2, varscan2
- CCDC88B | c.*212C>T | 3'UTR (SNP) | VAF 14/124 reads (11%) | catalogued as rs762147874; called by muse, mutect2, varscan2
- CD163L1 | c.-4C>A | 5'UTR (SNP) | VAF 131/313 reads (42%) | catalogued as rs769240126; called by muse, mutect2, varscan2
- CPNE8 | chr12:38907372 A>C | 5'Flank (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- CYP11B1 | c.955-70C>T | Intron (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- DCHS2 | n.2653-794T>C | Intron (SNP) | VAF 87/312 reads (28%) | called by muse, mutect2, varscan2
- DIAPH1 | c.-46C>T | 5'UTR (SNP) | VAF 15/27 reads (56%) | catalogued as rs1442560211; called by muse, mutect2, varscan2
- DYSF | c.458-421C>A | Intron (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- ERICH3 | c.-12G>C | 5'UTR (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- GCA | c.*550C>T | 3'UTR (SNP) | VAF 14/39 reads (36%) | catalogued as rs1025068568; called by muse, mutect2, varscan2
- HSPA1B | chr6:31835064 G>C | 3'Flank (SNP) | VAF 28/48 reads (58%) | catalogued as rs1241599733; called by muse, mutect2, varscan2
- HTR5A | chr7:155069231 G>A | 5'Flank (SNP) | VAF 24/168 reads (14%) | called by muse, mutect2, varscan2
- KANSL2 | c.1228-1712A>G | Intron (SNP) | VAF 55/145 reads (38%) | called by muse, mutect2, varscan2
- KCNQ2 | c.817-27G>A | Intron (SNP) | VAF 54/96 reads (56%) | catalogued as rs764858877; called by muse, mutect2, varscan2
- KRAS | c.450+28C>T | Intron (SNP) | VAF 104/267 reads (39%) | catalogued as COSV55797103; called by muse, mutect2, varscan2
- LIG1 | c.*37G>A | 3'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- MIR521-1 | n.48G>T | RNA (SNP) | VAF 10/155 reads (6%) | called by muse, mutect2
- MXD3 | c.506-24C>T | Intron (SNP) | VAF 19/36 reads (53%) | called by muse, mutect2, varscan2
- NBPF7 | n.185G>T | RNA (SNP) | VAF 106/180 reads (59%) | called by muse, mutect2, varscan2
- NCF1B | n.478T>A | RNA (SNP) | VAF 98/178 reads (55%) | called by muse, mutect2, varscan2
- NDUFA9 | c.50-666C>G | Intron (SNP) | VAF 48/170 reads (28%) | called by muse, mutect2, varscan2
- OR9Q1 | c.-15+53283A>G | Intron (SNP) | VAF 71/203 reads (35%) | called by muse, mutect2, varscan2
- PABPC1P2 | n.657G>T | RNA (SNP) | VAF 135/459 reads (29%) | called by muse, mutect2, varscan2
- PANK3 | c.-12C>T | 5'UTR (SNP) | VAF 9/16 reads (56%) | catalogued as rs1269978931, COSV53322481; called by muse, varscan2
- PATJ | c.*1937G>C | 3'UTR (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- PPHLN1 | c.72+7888C>A | Intron (SNP) | VAF 10/118 reads (8%) | catalogued as rs1230430902; called by muse, mutect2
- PPWD1 | c.300-696G>C | Intron (SNP) | VAF 108/257 reads (42%) | called by muse, mutect2, varscan2
- RANBP3L | c.*3A>G | 3'UTR (SNP) | VAF 99/351 reads (28%) | called by muse, mutect2, varscan2
- RFX3 | c.215+1811T>G | Intron (SNP) | VAF 49/138 reads (36%) | catalogued as rs746117014; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791127 C>G | 5'Flank (SNP) | VAF 77/103 reads (75%) | called by muse, mutect2, varscan2
- RPS27 | c.-6G>T | 5'UTR (SNP) | VAF 45/180 reads (25%) | called by muse, mutect2, varscan2
- SCOC-AS1 | n.139+25619G>C | Intron (SNP) | VAF 36/210 reads (17%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-15146G>A | Intron (SNP) | VAF 70/410 reads (17%) | called by muse, mutect2, varscan2
- SNORD116-6 | n.5C>A | RNA (SNP) | VAF 76/119 reads (64%) | called by muse, mutect2, varscan2
- THOC5 | c.97-539C>T | Intron (SNP) | VAF 40/122 reads (33%) | catalogued as rs927830151; called by muse, mutect2, varscan2
- TMEM221 | chr19:17433444 A>T | 3'Flank (SNP) | VAF 73/191 reads (38%) | called by muse, mutect2, varscan2
- TPI1 | c.227-551G>C | Intron (SNP) | VAF 108/466 reads (23%) | called by muse, varscan2
- TTN | c.10360+2151C>G | Intron (SNP) | VAF 43/156 reads (28%) | called by muse, mutect2, varscan2
- TUBB7P | n.50G>T | RNA (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- XKR6 | c.764+76489A>C | Intron (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- ZNF17 | c.15+12G>T | Intron (SNP) | VAF 18/32 reads (56%) | called by muse, mutect2, varscan2
